Somatic mutation profile of tumor specimen C3L-08247-02 (aliquot CPT0497800006) from CPTAC case C3L-08247, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.7 years (19,604 days).
Specimen C3L-08247-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) feb7a422-aa03-417c-8b1e-04925e084811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08247-31 (Blood Derived Normal), aliquot CPT0497940002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26e68ec7-2241-435f-8209-e3d6f4e6c5f6

The open-access MAF lists 78 somatic variants for this specimen: 55 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Intron 2, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.1153C>G p.P385A | Missense Mutation (SNP) | VAF 19/377 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as COSV65427316; called by muse, mutect2
- ANKRD11 | c.4630G>A p.D1544N | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.763); catalogued as rs761378635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP15 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 66/394 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs1557280374, COSV53142274; called by muse, mutect2, varscan2
- CDH2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1323181717; called by muse, mutect2
- CLDN17 | c.252G>T p.M84I | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54522410; called by muse, mutect2
- CSF2RA | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 47/506 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs761247845, COSV62623495; called by muse, mutect2
- CYHR1 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 23/425 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs770969459; called by muse, mutect2
- DGAT2L6 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 31/583 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60717817; called by muse, mutect2
- DMRTB1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1032368771, COSV65113036; called by muse, mutect2
- DNAH2 | c.8054G>C p.C2685S | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV66728810; called by muse, mutect2
- DUSP16 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 37/459 reads (8%) | catalogued as COSV53806900; called by muse, mutect2
- EBF4 | c.247G>A p.V83M (on ENST00000609451; = p.V79M on NM_001110514.1) | Missense Mutation (SNP) | VAF 14/399 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1415653447; called by muse, mutect2
- EPHA4 | c.1105T>C p.C369R | Missense Mutation (SNP) | VAF 31/469 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168279571; called by muse, mutect2
- GPR143 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 83/513 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs1281289432; called by muse, mutect2, varscan2
- GRIN3A | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 42/473 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62458800; called by muse, mutect2
- KANSL1 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 36/557 reads (6%) | catalogued as COSV52264743; called by muse, mutect2
- LNX1 | c.1070G>A p.R357H (on ENST00000263925 / NM_001126328.3; = p.R261H on NM_032622.2) | Missense Mutation (SNP) | VAF 36/536 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778438694, COSV55791219, COSV99820336; called by muse, mutect2
- MAGEL2 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 46/651 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as rs1341435115; called by muse, mutect2
- MAP1B | c.3478G>A p.V1160I | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs773567258, COSV57106040; called by muse, mutect2
- MEI1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs759100618, COSV55905264; called by muse, mutect2
- MTMR1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1412495806; called by muse, varscan2
- NAB2 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 36/484 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.919); catalogued as rs1367546982; called by muse, mutect2
- NOS2 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 29/439 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs200678947; called by muse, mutect2
- NUMA1 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 31/556 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs367866725; called by muse, mutect2
- NUP210L | c.2158C>T p.R720W | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs909755703, COSV99668697; called by muse, mutect2
- OR5R1 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs1351859762; called by muse, mutect2
- POLA1 | c.2336C>T p.T779M | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99075068; called by muse, mutect2
- PPP2R5B | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 45/572 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs137914776; called by muse, mutect2
- SEPTIN9 | c.1255G>A p.G419S (on ENST00000427177 / NM_001113491.2; = p.G401S on NM_006640.4) | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1431233902, COSV61203938; called by muse, mutect2
- SLC35C1 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 42/478 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770499899; called by muse, mutect2
- SMC1A | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.691); catalogued as rs1556890833; ClinVar: uncertain significance; called by muse, mutect2
- SPAG17 | c.5716C>T p.R1906C | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs888556091, COSV60462109; called by muse, mutect2
- SULT2B1 | c.358C>T p.R120C (on ENST00000201586 / NM_177973.2; = p.R105C on NM_004605.2) | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1027668633; called by muse, mutect2
- VWC2L | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775492537; called by muse, mutect2
- ZNF512B | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 48/624 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs946248668; called by muse, mutect2
- AQP6 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 47/450 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATF7IP2 | c.1709C>T p.T570I | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 38/530 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); called by muse, mutect2
- CDH18 | c.2315C>A p.P772H | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP295 | c.3007A>G p.T1003A | Missense Mutation (SNP) | VAF 26/395 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- CHM | c.54G>C p.L18F | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- ENPP5 | c.163A>T p.M55L | Missense Mutation (SNP) | VAF 33/392 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- FMN2 | c.1457C>A p.T486K | Missense Mutation (SNP) | VAF 27/666 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- KIAA1549L | c.3858G>A p.K1286= (on ENST00000321505; = p.K1583= on NM_012194.3) | Splice Region (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- LGR4 | c.1426dup p.C476Lfs*2 | Frame Shift Ins (INS) | VAF 32/322 reads (10%) | called by mutect2, pindel
- LUC7L | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MYO5B | c.3725T>C p.L1242P | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2
- P3H3 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 23/413 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- PHOX2B | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 31/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PORCN | c.16C>A p.R6S | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRAG1 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 50/725 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.791); called by muse, mutect2
- SHROOM2 | c.3631C>G p.P1211A | Missense Mutation (SNP) | VAF 35/500 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC2A13 | c.1273A>C p.K425Q | Missense Mutation (SNP) | VAF 17/278 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- UNC13C | c.6353T>G p.F2118C | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF37A | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 58/452 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ADARB2 | c.477G>A p.A159= | Silent (SNP) | VAF 74/532 reads (14%) | catalogued as COSV67222062; called by muse, mutect2, varscan2
- APBB2 | c.1515C>T p.R505= (on ENST00000295974 / NM_001166050.2; = p.R506= on NM_004307.2) | Silent (SNP) | VAF 24/334 reads (7%) | catalogued as rs377258984; called by muse, mutect2
- ARMH1 | c.1173G>A p.A391= | Silent (SNP) | VAF 19/371 reads (5%) | called by muse, mutect2
- CEP97 | c.1989G>A p.S663= | Silent (SNP) | VAF 18/276 reads (7%) | catalogued as rs1270128869, COSV59128306; called by muse, mutect2
- CHRNA4 | c.1500C>T p.P500= | Silent (SNP) | VAF 33/578 reads (6%) | catalogued as rs201391859, COSV64719943; ClinVar: likely benign; called by muse, mutect2
- ELAVL2 | c.771T>A p.I257= | Silent (SNP) | VAF 15/278 reads (5%) | called by muse, mutect2
- FGD5 | c.1515G>A p.A505= | Silent (SNP) | VAF 45/503 reads (9%) | catalogued as rs371123682; called by muse, mutect2
- HCN1 | c.552A>C p.T184= | Silent (SNP) | VAF 33/336 reads (10%) | called by muse, mutect2
- MTMR1 | c.1050C>A p.T350= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- MYO1G | c.1431C>T p.T477= | Silent (SNP) | VAF 41/443 reads (9%) | catalogued as rs775539464; called by muse, mutect2
- NUBP1 | c.549C>T p.V183= | Silent (SNP) | VAF 39/447 reads (9%) | catalogued as rs567909347; called by muse, mutect2
- OR8H2 | c.534C>T p.F178= | Silent (SNP) | VAF 30/410 reads (7%) | catalogued as COSV57944814; called by muse, mutect2
- PCDHB8 | c.2130G>A p.V710= | Silent (SNP) | VAF 37/641 reads (6%) | called by muse, mutect2
- PCDHGA6 | c.2208C>A p.P736= | Silent (SNP) | VAF 27/564 reads (5%) | called by muse, mutect2
- PGA3 | c.153A>G p.R51= | Silent (SNP) | VAF 41/518 reads (8%) | called by muse, mutect2
- PGR | c.372C>T p.P124= | Silent (SNP) | VAF 31/453 reads (7%) | catalogued as rs1180129442, COSV99677370; called by muse, mutect2
- RPTN | c.423C>T p.D141= | Silent (SNP) | VAF 39/607 reads (6%) | catalogued as rs565256584, COSV60167666; called by muse, mutect2
- SPTBN1 | c.6555C>T p.A2185= | Silent (SNP) | VAF 37/467 reads (8%) | catalogued as rs138252002; called by muse, mutect2
- ZNF831 | c.1452C>T p.F484= | Silent (SNP) | VAF 46/542 reads (8%) | called by muse, mutect2
- AL021408.1 | n.291A>T | RNA (SNP) | VAF 23/346 reads (7%) | called by muse, mutect2
- AL132655.6 | chr20:58841961 C>T | 5'Flank (SNP) | VAF 12/355 reads (3%) | called by muse, mutect2
- ARHGAP28 | c.2030+1921C>A | Intron (SNP) | VAF 19/296 reads (6%) | called by muse, mutect2
- ST3GAL3 | c.164-20187G>T | Intron (SNP) | VAF 21/307 reads (7%) | called by muse, mutect2
